Somatic mutation profile of tumor specimen 0DF3JS from CCDI case PBBRIA, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Frontal lobe; Age at diagnosis: 13.5 years (4,925 days).
Specimen 0DF3JS: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b4b3972b-1418-4fe7-9ca5-315f99846c30.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DF3K1 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2f5083b6-106e-46b5-a2c8-e38e3d637ebb

The open-access MAF lists 6 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Silent 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MRC2 | c.1202G>A p.R401H | Missense Mutation (SNP) | VAF 137/414 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs749243892, COSV57642873; called by muse, mutect2, varscan2
- SNED1 | c.865G>A p.V289I | Missense Mutation (SNP) | VAF 167/572 reads (29%) | SIFT tolerated (0.84); PolyPhen benign (0.144); catalogued as rs200538396; called by muse, mutect2, varscan2
- TYMP | c.1073G>A p.R358Q | Missense Mutation (SNP) | VAF 75/288 reads (26%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as rs1209463945; called by muse, mutect2, varscan2
- CSMD3 | c.9910G>A p.G3304S (on ENST00000297405 / NM_001363185.1; = p.G3135S on NM_052900.3) | Missense Mutation (SNP) | VAF 234/885 reads (26%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- SLCO1B1 | c.657T>A p.G219= | Silent (SNP) | VAF 37/1277 reads (3%) | called by muse, mutect2
- TUBA1A | c.376-77G>T | Intron (SNP) | VAF 29/82 reads (35%) | called by muse, mutect2, varscan2
